Somatic mutation profile of tumor specimen ALCH-B43S-TTP1-A (aliquot ALCH-B43S-TTP1-A-1-0-D-A80E-36) from ALCHEMIST case ALCH-B43S, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 78.8 years (28,772 days).
Specimen ALCH-B43S-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5722d6a4-d6ac-4334-a979-8494d1c81d03.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B43S-NB1-A (Blood Derived Normal), aliquot ALCH-B43S-NB1-A-1-0-D-A80E-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b3ca781a-3c68-4819-9431-754d7da4d3c3

The open-access MAF lists 241 somatic variants for this specimen: 147 protein-altering or splice-affecting, 59 silent, 35 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 121, Silent 59, Intron 21, Nonsense Mutation 14, RNA 7, Frame Shift Del 4, Splice Region 4, 3'UTR 3, Frame Shift Ins 2, 5'UTR 2, 5'Flank 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.98C>G p.S33C | Missense Mutation (SNP) | VAF 42/442 reads (10%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913400, COSV62687839, COSV62688300, COSV62688644; ClinVar: likely pathogenic /  other; called by muse, mutect2
- AC004997.1 | c.1421G>A p.R474Q | Missense Mutation (SNP) | VAF 6/157 reads (4%) | SIFT tolerated, low confidence (0.33); catalogued as rs1303416764, COSV57576346; called by muse, mutect2
- AK5 | c.726C>A p.F242L (on ENST00000354567 / NM_174858.3; = p.F216L on NM_012093.4) | Missense Mutation (SNP) | VAF 10/156 reads (6%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.944); catalogued as COSV60983718; called by muse, mutect2
- ASIC2 | c.184G>A p.E62K | Missense Mutation (SNP) | VAF 20/144 reads (14%) | SIFT tolerated (0.36); PolyPhen benign (0.142); catalogued as COSV100726564; called by muse, mutect2, varscan2
- BNC1 | c.1688C>A p.S563* | Nonsense Mutation (SNP) | VAF 49/465 reads (11%) | catalogued as COSV100597469, COSV100597516; called by muse, mutect2, varscan2
- CADPS2 | c.1227G>T p.W409C | Missense Mutation (SNP) | VAF 35/241 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57389633; called by muse, mutect2, varscan2
- CHSY3 | c.2189G>A p.R730Q | Missense Mutation (SNP) | VAF 29/253 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV59285928; called by muse, mutect2, varscan2
- CNTNAP2 | c.786C>A p.H262Q | Missense Mutation (SNP) | VAF 56/461 reads (12%) | SIFT tolerated (0.55); PolyPhen benign (0.27); catalogued as COSV62155886; called by muse, mutect2, varscan2
- DCHS1 | c.9883G>A p.E3295K | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54995863; called by muse, mutect2, varscan2
- DMXL2 | c.4720C>T p.R1574C | Missense Mutation (SNP) | VAF 16/304 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759997371; called by muse, mutect2
- DNAH3 | c.3430G>C p.E1144Q | Missense Mutation (SNP) | VAF 37/275 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.403); catalogued as COSV54501144, COSV54533273; called by muse, mutect2, varscan2
- DNAI2 | c.68G>A p.R23H | Missense Mutation (SNP) | VAF 25/158 reads (16%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.912); catalogued as rs755972641, COSV56757330; called by muse, mutect2, varscan2
- FNDC7 | c.604C>T p.R202W | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.513); catalogued as rs746928344; called by muse, mutect2, varscan2
- FUS | c.1471C>T p.R491C | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.549); catalogued as rs753458243, CM1510998; called by muse, mutect2, varscan2
- GABRG2 | c.226G>A p.G76R | Missense Mutation (SNP) | VAF 45/455 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100729873; called by muse, mutect2, varscan2
- GABRG2 | c.227G>T p.G76V | Missense Mutation (SNP) | VAF 44/471 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62723536; called by muse, mutect2
- GAPDHS | c.644C>A p.S215Y | Missense Mutation (SNP) | VAF 38/80 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.751); catalogued as rs761240119; called by muse, mutect2, varscan2
- GARNL3 | c.466A>G p.S156G | Missense Mutation (SNP) | VAF 24/255 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.02); catalogued as rs774224753; called by muse, mutect2
- GDF10 | c.439G>C p.E147Q | Missense Mutation (SNP) | VAF 14/156 reads (9%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.448); catalogued as rs782809728; called by muse, mutect2, varscan2
- GDF9 | c.209C>G p.S70C | Missense Mutation (SNP) | VAF 28/204 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.011); catalogued as rs933014086, COSV51525851, COSV99737546; called by muse, mutect2, varscan2
- GDF9 | c.97C>G p.Q33E | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.052); catalogued as rs765564948; called by muse, mutect2, varscan2
- GPATCH2L | c.1247G>T p.R416L | Missense Mutation (SNP) | VAF 41/400 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV55052533; called by muse, mutect2, varscan2
- GRM1 | c.718G>A p.G240R | Missense Mutation (SNP) | VAF 11/291 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51125718; called by muse, mutect2
- HGF | c.1939C>T p.R647* | Nonsense Mutation (SNP) | VAF 58/515 reads (11%) | catalogued as rs545249104, COSV55956856; called by muse, mutect2, varscan2
- HOXD11 | c.508C>T p.R170C | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50912605; called by muse, mutect2, varscan2
- HTATIP2 | c.373A>T p.K125* | Nonsense Mutation (SNP) | VAF 39/292 reads (13%) | catalogued as rs754157913; called by muse, mutect2, varscan2
- HTR1A | c.1189C>A p.P397T | Missense Mutation (SNP) | VAF 20/143 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60502922; called by muse, mutect2, varscan2
- KEAP1 | c.756G>T p.W252C | Missense Mutation (SNP) | VAF 16/143 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV50274462, COSV50300442; called by muse, mutect2, varscan2
- KEAP1 | c.755G>T p.W252L | Missense Mutation (SNP) | VAF 16/143 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV50344880; called by muse, mutect2, varscan2
- KMT2A | c.7340del p.L2447Wfs*6 | Frame Shift Del (DEL) | VAF 12/106 reads (11%) | catalogued as COSV63291880; called by mutect2, pindel, varscan2
- LIPC | c.902C>T p.P301L | Missense Mutation (SNP) | VAF 63/316 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV54428006; called by muse, mutect2, varscan2
- MAPK15 | c.1514C>G p.S505C | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.785); catalogued as rs1330909148, COSV62027967; called by muse, mutect2, varscan2
- MPI | c.62T>A p.M21K | Missense Mutation (SNP) | VAF 30/232 reads (13%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs778966484; called by muse, mutect2, varscan2
- MYO5A | c.2546G>A p.R849Q | Missense Mutation (SNP) | VAF 60/382 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs754654495, COSV62564531; called by muse, mutect2, varscan2
- NAA30 | c.681C>G p.I227M | Missense Mutation (SNP) | VAF 27/189 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.325); catalogued as COSV100035765; called by muse, mutect2, varscan2
- NAALAD2 | c.1550G>A p.R517K | Missense Mutation (SNP) | VAF 25/294 reads (9%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.617); catalogued as COSV58959701; called by muse, mutect2
- NHS | c.460G>C p.E154Q | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs1156244479; called by muse, mutect2, varscan2
- NPAS2 | c.1226C>T p.S409L | Missense Mutation (SNP) | VAF 25/199 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs564795063, COSV59561142; called by muse, mutect2, varscan2
- OR11H1 | c.751G>C p.V251L | Missense Mutation (SNP) | VAF 43/520 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.447); catalogued as COSV99421867; called by muse, mutect2, varscan2
- OR5M11 | c.866A>G p.Y289C | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.557); catalogued as COSV101602067; called by muse, mutect2
- ORC4 | c.938C>T p.S313L | Missense Mutation (SNP) | VAF 29/480 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.253); catalogued as rs752102540; called by muse, mutect2
- OSR2 | c.41C>A p.P14Q | Missense Mutation (SNP) | VAF 26/209 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as rs764701063, COSV52556072; called by muse, mutect2, varscan2
- OVCH1 | c.31C>A p.L11M | Missense Mutation (SNP) | VAF 51/210 reads (24%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.444); catalogued as COSV99758846; called by muse, mutect2, varscan2
- PAFAH1B1 | c.1160-3C>G | Splice Region (SNP) | VAF 39/230 reads (17%) | catalogued as COSV68210193; called by muse, varscan2
- PCDHB8 | c.522C>A p.S174R | Missense Mutation (SNP) | VAF 30/614 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.878); catalogued as COSV50809322; called by muse, mutect2
- RBM10 | c.2282G>C p.C761S | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61312475; called by muse, mutect2, varscan2
- RCAN1 | c.110C>T p.S37L | Missense Mutation (SNP) | VAF 18/149 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV58249993, COSV58250681; called by muse, mutect2, varscan2
- RIIAD1 | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.142); catalogued as COSV51884950, COSV51885528; called by muse, mutect2, varscan2
- RPGRIP1 | c.3461C>T p.S1154L | Missense Mutation (SNP) | VAF 26/207 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as rs188312873; called by muse, mutect2, varscan2
- SEMA3D | c.1946G>A p.G649E | Missense Mutation (SNP) | VAF 17/150 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99407694; called by muse, varscan2
- SEMA4F | c.244C>T p.R82W | Missense Mutation (SNP) | VAF 24/151 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs140925977, COSV60282287; called by muse, mutect2, varscan2
- SHANK2 | c.2534G>A p.R845Q | Missense Mutation (SNP) | VAF 32/127 reads (25%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.49); catalogued as rs782015001, COSV53585885; ClinVar: uncertain significance; called by mutect2, varscan2
- SIRT1 | c.1609G>A p.D537N | Missense Mutation (SNP) | VAF 39/372 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as rs1308551562; called by muse, mutect2, varscan2
- SLC17A6 | c.232G>T p.G78C | Missense Mutation (SNP) | VAF 47/317 reads (15%) | SIFT tolerated (0.41); PolyPhen benign (0.053); catalogued as COSV54134347; called by muse, mutect2, varscan2
- SRGAP3 | c.1300G>A p.E434K | Missense Mutation (SNP) | VAF 39/295 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV64531169, COSV64542042; called by muse, mutect2, varscan2
- ST6GALNAC3 | c.228C>G p.D76E | Missense Mutation (SNP) | VAF 13/94 reads (14%) | PolyPhen benign (0.103); catalogued as COSV60328642; called by muse, mutect2, varscan2
- TAF3 | c.364G>T p.E122* | Nonsense Mutation (SNP) | VAF 18/160 reads (11%) | catalogued as COSV60203131; called by muse, mutect2
- TG | c.4552G>A p.E1518K | Missense Mutation (SNP) | VAF 128/529 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs200687678, COSV99602604; called by muse, mutect2, varscan2
- TGFBI | c.1437C>G p.I479M | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT tolerated (0.95); PolyPhen probably damaging (0.977); catalogued as COSV100526213; called by muse, mutect2
- TLR4 | c.800G>T p.G267V (on ENST00000355622 / NM_138554.5; = p.G227V on NM_003266.4) | Missense Mutation (SNP) | VAF 54/535 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as COSV62924103; called by muse, mutect2
- TMEM132B | c.496G>A p.E166K | Missense Mutation (SNP) | VAF 20/173 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV54757496, COSV54762045; called by muse, mutect2, varscan2
- TMEM132E | c.2680C>T p.H894Y (on ENST00000321639; = p.H984Y on NM_001304438.2) | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated (0.42); PolyPhen benign (0.009); catalogued as rs1432623790; called by muse, mutect2, varscan2
- UGT1A7 | c.283G>A p.D95N | Missense Mutation (SNP) | VAF 49/416 reads (12%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs761343712, COSV60839632; called by muse, mutect2, varscan2
- ULK4 | c.3120+1G>T p.X1040_splice | Splice Site (SNP) | VAF 10/148 reads (7%) | catalogued as COSV100093718; called by muse, mutect2
- YY1AP1 | c.581C>T p.P194L (on ENST00000295566 / NM_139118.2; = p.P117L on NM_018253.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/437 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs771511749; called by muse, mutect2
- ZDHHC12 | c.532G>T p.G178W | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as rs779856643, COSV52578358; called by muse, mutect2, varscan2
- ZSCAN5A | c.601C>G p.L201V | Missense Mutation (SNP) | VAF 73/216 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.411); catalogued as rs761986359; called by muse, mutect2, varscan2
- ABCA1 | c.3497G>T p.G1166V | Missense Mutation (SNP) | VAF 82/521 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- ADAMTSL1 | c.2977C>T p.Q993* | Nonsense Mutation (SNP) | VAF 10/69 reads (14%) | called by muse, mutect2, varscan2
- ADGRB3 | c.2775T>A p.N925K | Missense Mutation (SNP) | VAF 12/169 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ADGRG4 | c.2902G>A p.A968T | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANKRD36B | c.411A>T p.K137N | Missense Mutation (SNP) | VAF 24/250 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.061); called by muse, varscan2
- ATG14 | c.1066C>G p.L356V | Missense Mutation (SNP) | VAF 14/123 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ATP2B3 | c.1786C>G p.L596V | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.63); PolyPhen benign (0.031); called by muse, varscan2
- ATP8A1 | c.1504C>G p.Q502E | Missense Mutation (SNP) | VAF 45/387 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- AVL9 | c.1744T>C p.S582P | Missense Mutation (SNP) | VAF 42/245 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- BAIAP3 | c.2723C>G p.S908W | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- BCORL1 | c.1018C>T p.P340S | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT tolerated, low confidence (0.15); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- C2orf68 | c.108-8C>A | Splice Region (SNP) | VAF 21/102 reads (21%) | called by muse, mutect2, varscan2
- CARS2 | c.73G>T p.G25W | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- CDH8 | c.907C>A p.Q303K | Missense Mutation (SNP) | VAF 14/141 reads (10%) | SIFT tolerated (0.72); PolyPhen benign (0.003); called by muse, mutect2
- CDK5R1 | c.156G>T p.W52C | Missense Mutation (SNP) | VAF 17/114 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CEP170 | c.1339G>A p.E447K | Missense Mutation (SNP) | VAF 43/378 reads (11%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- CEP78 | c.1006A>C p.K336Q | Missense Mutation (SNP) | VAF 18/133 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- CFAP91 | c.2086G>T p.E696* | Nonsense Mutation (SNP) | VAF 35/355 reads (10%) | called by muse, mutect2
- DAG1 | c.55C>T p.L19F | Missense Mutation (SNP) | VAF 30/255 reads (12%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- DCSTAMP | c.438G>T p.E146D | Missense Mutation (SNP) | VAF 60/278 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- DIPK1C | c.397G>C p.E133Q | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- DOT1L | c.2039del p.G680Afs*25 | Frame Shift Del (DEL) | VAF 11/89 reads (12%) | called by mutect2, pindel, varscan2
- ERAP1 | c.685G>A p.E229K | Missense Mutation (SNP) | VAF 42/350 reads (12%) | SIFT tolerated (0.46); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- EVI5L | c.2048C>G p.S683W | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- F2RL2 | c.880C>G p.H294D | Missense Mutation (SNP) | VAF 26/164 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FAT3 | c.4181G>T p.W1394L | Missense Mutation (SNP) | VAF 9/106 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- GBP3 | c.190+7G>A | Splice Region (SNP) | VAF 39/329 reads (12%) | called by muse, mutect2, varscan2
- GBP5 | c.197C>T p.S66F | Missense Mutation (SNP) | VAF 26/230 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- GOLGA7 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 10/65 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); called by muse, varscan2
- GOLGA7 | c.97G>A p.E33K | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); called by muse, varscan2
- HEXIM1 | c.883G>C p.E295Q | Missense Mutation (SNP) | VAF 66/339 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- IFFO2 | c.842C>G p.T281R | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.462); called by muse, mutect2, varscan2
- IFT122 | c.3077A>G p.Y1026C (on ENST00000348417 / NM_052989.3; = p.Y967C on NM_018262.4) | Missense Mutation (SNP) | VAF 22/224 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- ING4 | c.447C>G p.N149K (on ENST00000396807 / NM_001127582.2; = p.N148K on NM_016162.4) | Missense Mutation (SNP) | VAF 37/159 reads (23%) | SIFT tolerated (0.42); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KCNAB1 | c.572G>C p.G191A (on ENST00000490337 / NM_172160.3; = p.G180A on NM_003471.3) | Missense Mutation (SNP) | VAF 31/307 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.884); called by muse, mutect2, varscan2
- KRBA2 | c.1107G>C p.K369N | Missense Mutation (SNP) | VAF 15/129 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.67); called by muse, mutect2, varscan2
- LARP1 | c.2462G>T p.R821I (on ENST00000518297 / NM_033551.3; = p.R744I on NM_015315.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/185 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.519); called by muse, mutect2, varscan2
- LDB2 | c.346A>T p.I116F | Missense Mutation (SNP) | VAF 36/292 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); called by muse, mutect2, varscan2
- LOXHD1 | c.3799C>A p.L1267I | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.537); called by muse, mutect2, varscan2
- LTK | c.2060T>A p.V687D | Missense Mutation (SNP) | VAF 8/95 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- MCC | c.978dup p.A327Cfs*2 | Frame Shift Ins (INS) | VAF 28/261 reads (11%) | called by mutect2, pindel, varscan2
- MEOX1 | c.570T>A p.F190L | Missense Mutation (SNP) | VAF 20/143 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MPI | c.63G>T p.M21I | Missense Mutation (SNP) | VAF 30/234 reads (13%) | SIFT tolerated (0.67); PolyPhen benign (0); called by muse, mutect2, varscan2
- MROH1 | c.4227G>A p.M1409I | Missense Mutation (SNP) | VAF 33/197 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MROH2B | c.4032A>C p.L1344F | Missense Mutation (SNP) | VAF 17/117 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.146); called by muse, mutect2
- MUC5AC | c.14237C>A p.A4746D | Missense Mutation (SNP) | VAF 25/171 reads (15%) | SIFT tolerated, low confidence (0.2); PolyPhen possibly damaging (0.653); called by muse, mutect2, varscan2
- NCAM1 | c.1195A>G p.N399D (on ENST00000316851 / NM_181351.5; = p.N389D on NM_000615.7) | Missense Mutation (SNP) | VAF 22/175 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.697); called by muse, mutect2, varscan2
- NIN | c.1246G>T p.E416* | Nonsense Mutation (SNP) | VAF 14/93 reads (15%) | called by muse, mutect2, varscan2
- NRXN1 | c.2777C>T p.S926F | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- OLFML2A | c.1036G>C p.E346Q | Missense Mutation (SNP) | VAF 26/250 reads (10%) | SIFT tolerated (0.37); PolyPhen benign (0.237); called by muse, mutect2
- OR14K1 | c.716G>T p.C239F | Missense Mutation (SNP) | VAF 25/252 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- OR56B4 | c.414C>A p.Y138* | Nonsense Mutation (SNP) | VAF 18/132 reads (14%) | called by muse, mutect2, varscan2
- OR6K2 | c.443del p.C148Lfs*49 | Frame Shift Del (DEL) | VAF 7/62 reads (11%) | called by mutect2, pindel, varscan2
- PCDHB15 | c.2089G>A p.V697M | Missense Mutation (SNP) | VAF 36/311 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- PKD2L1 | c.1000dup p.W334Lfs*23 | Frame Shift Ins (INS) | VAF 35/231 reads (15%) | called by mutect2, pindel, varscan2
- POC1B-GALNT4 | c.1412T>C p.L471P | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- PTK2 | c.1190A>G p.Y397C | Missense Mutation (SNP) | VAF 31/151 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RBBP7 | c.791C>G p.P264R | Missense Mutation (SNP) | VAF 49/175 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- RGL1 | c.1741C>T p.Q581* (on ENST00000360851 / NM_001297672.2; = p.Q616* on NM_015149.5 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 8/107 reads (7%) | called by muse, mutect2
- SLC39A9 | c.473-4A>G | Splice Region (SNP) | VAF 31/189 reads (16%) | called by muse, mutect2, varscan2
- SMC3 | c.679A>G p.I227V | Missense Mutation (SNP) | VAF 29/267 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.858); called by muse, mutect2, varscan2
- SRPX | c.430G>T p.E144* | Nonsense Mutation (SNP) | VAF 32/131 reads (24%) | called by muse, mutect2, varscan2
- ST18 | c.1198C>A p.L400M | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.812); called by muse, mutect2, varscan2
- STARD9 | c.3278C>G p.S1093* | Nonsense Mutation (SNP) | VAF 17/145 reads (12%) | called by muse, mutect2, varscan2
- STK11 | c.899T>A p.I300N | Missense Mutation (SNP) | VAF 54/126 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SYNJ1 | c.2951G>A p.G984E | Missense Mutation (SNP) | VAF 20/239 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); called by muse, mutect2
- TEAD3 | c.61G>C p.E21Q | Missense Mutation (SNP) | VAF 21/140 reads (15%) | SIFT tolerated (0.36); PolyPhen benign (0.189); called by muse, mutect2, varscan2
- TEKT5 | c.697C>G p.Q233E | Missense Mutation (SNP) | VAF 26/235 reads (11%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- TLR4 | c.799G>T p.G267* (on ENST00000355622 / NM_138554.5; = p.G227* on NM_003266.4) | Nonsense Mutation (SNP) | VAF 50/494 reads (10%) | called by muse, varscan2
- TMEM132E | c.196C>G p.P66A | Missense Mutation (SNP) | VAF 20/204 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2
- TRIM15 | c.205C>T p.P69S | Missense Mutation (SNP) | VAF 18/180 reads (10%) | SIFT tolerated (0.75); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TTC3 | c.746T>A p.I249K | Missense Mutation (SNP) | VAF 18/154 reads (12%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.773); called by muse, mutect2
- UBE3B | c.2080G>T p.G694C | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- UBXN7 | c.1294C>T p.Q432* | Nonsense Mutation (SNP) | VAF 34/253 reads (13%) | called by muse, mutect2, varscan2
- UNK | c.1043C>G p.S348C | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.536); called by muse, mutect2, varscan2
- YIPF1 | c.769G>T p.V257F | Missense Mutation (SNP) | VAF 21/219 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.168); called by muse, mutect2
- YTHDC1 | c.1352G>T p.R451L (on ENST00000344157 / NM_001031732.4; = p.R433L on NM_133370.4) | Missense Mutation (SNP) | VAF 23/161 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.767); called by muse, mutect2, varscan2
- ZNF337 | c.1876C>T p.Q626* | Nonsense Mutation (SNP) | VAF 17/122 reads (14%) | called by muse, mutect2, varscan2
- ZNF593 | c.287_288del p.P96Lfs*30 | Frame Shift Del (DEL) | VAF 41/310 reads (13%) | called by mutect2, pindel, varscan2
- ZNF717 | c.1904G>T p.S635I | Missense Mutation (SNP) | VAF 21/270 reads (8%) | SIFT tolerated (0.79); PolyPhen benign (0.053); called by muse, mutect2
- ACSBG2 | c.1146C>A p.V382= | Silent (SNP) | VAF 19/175 reads (11%) | called by muse, mutect2, varscan2
- ADAMTS14 | c.324C>T p.F108= | Silent (SNP) | VAF 30/282 reads (11%) | called by muse, mutect2, varscan2
- ADGRL3 | c.4452C>A p.P1484= (on ENST00000506720 / NM_001322402.2; = p.P1373= on NM_015236.6) | Silent (SNP) | VAF 44/399 reads (11%) | catalogued as rs548907641; called by muse, mutect2, varscan2
- AQR | c.3801G>A p.Q1267= | Silent (SNP) | VAF 31/251 reads (12%) | catalogued as COSV99334191; called by muse, mutect2, varscan2
- ARHGEF33 | c.111C>T p.F37= | Silent (SNP) | VAF 24/132 reads (18%) | catalogued as COSV67257818; called by muse, mutect2, varscan2
- ATP10D | c.3769C>T p.L1257= | Silent (SNP) | VAF 12/144 reads (8%) | called by muse, mutect2
- BRIX1 | c.189C>T p.L63= | Silent (SNP) | VAF 21/174 reads (12%) | catalogued as rs1159505314; called by muse, mutect2, varscan2
- CFLAR | c.1224G>T p.A408= | Silent (SNP) | VAF 39/221 reads (18%) | called by muse, mutect2, varscan2
- CRAT | c.852C>T p.F284= | Silent (SNP) | VAF 13/71 reads (18%) | called by muse, mutect2, varscan2
- CREB5 | c.834G>T p.P278= (on ENST00000357727 / NM_182898.4; = p.P271= on NM_004904.3) | Silent (SNP) | VAF 80/500 reads (16%) | catalogued as COSV100745528; called by muse, mutect2, varscan2
- DACH1 | c.594G>T p.V198= | Silent (SNP) | VAF 9/60 reads (15%) | called by muse, mutect2, varscan2
- DOCK10 | c.5904C>T p.F1968= | Silent (SNP) | VAF 58/399 reads (15%) | catalogued as rs768117264, COSV51379969; called by muse, mutect2, varscan2
- DTWD2 | c.603A>G p.Q201= | Silent (SNP) | VAF 19/105 reads (18%) | catalogued as rs780832774; called by muse, mutect2, varscan2
- E2F7 | c.1608G>T p.L536= | Silent (SNP) | VAF 41/168 reads (24%) | called by muse, mutect2, varscan2
- EPHB1 | c.1665C>T p.S555= | Silent (SNP) | VAF 18/186 reads (10%) | catalogued as COSV67669164; called by muse, mutect2
- HGS | c.402C>T p.I134= | Silent (SNP) | VAF 16/97 reads (16%) | called by muse, varscan2
- IMPG2 | c.2421G>A p.R807= | Silent (SNP) | VAF 31/233 reads (13%) | catalogued as rs767512719; called by muse, mutect2, varscan2
- IVD | c.738G>C p.L246= (on ENST00000651168; = p.L243= on NM_002225.5 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 53/374 reads (14%) | called by muse, mutect2, varscan2
- KBTBD7 | c.1089G>T p.S363= | Silent (SNP) | VAF 70/456 reads (15%) | catalogued as COSV65266955; called by muse, mutect2
- KMT2D | c.10869G>A p.Q3623= | Silent (SNP) | VAF 10/22 reads (45%) | called by muse, mutect2, varscan2
- KNTC1 | c.5019C>T p.T1673= | Silent (SNP) | VAF 36/288 reads (13%) | catalogued as rs756969253; called by muse, mutect2, varscan2
- LAMA5 | c.4149C>G p.V1383= | Silent (SNP) | VAF 10/41 reads (24%) | called by muse, mutect2, varscan2
- LRP12 | c.1656G>A p.L552= | Silent (SNP) | VAF 19/224 reads (8%) | catalogued as COSV52633651; called by muse, mutect2
- LRP1B | c.12183G>A p.L4061= | Silent (SNP) | VAF 39/249 reads (16%) | catalogued as rs772583073, COSV67249150; called by muse, mutect2, varscan2
- MINDY1 | c.1402C>T p.L468= | Silent (SNP) | VAF 11/114 reads (10%) | catalogued as rs774523136; called by muse, mutect2, varscan2
- MTERF3 | c.963G>A p.K321= | Silent (SNP) | VAF 26/270 reads (10%) | called by muse, mutect2
- MUC6 | c.1950C>A p.L650= | Silent (SNP) | VAF 14/73 reads (19%) | called by muse, mutect2
- MXRA8 | c.1317G>A p.E439= | Silent (SNP) | VAF 10/71 reads (14%) | catalogued as rs1199668878; called by muse, mutect2, varscan2
- NDST3 | c.720C>T p.T240= | Silent (SNP) | VAF 22/222 reads (10%) | called by muse, mutect2
- NOX3 | c.942C>G p.G314= | Silent (SNP) | VAF 19/105 reads (18%) | called by muse, mutect2
- NVL | c.1839G>A p.V613= | Silent (SNP) | VAF 38/412 reads (9%) | called by muse, mutect2
- OBSCN | c.9000G>T p.V3000= | Silent (SNP) | VAF 9/73 reads (12%) | called by muse, mutect2
- OR13H1 | c.480C>A p.I160= | Silent (SNP) | VAF 21/77 reads (27%) | called by muse, mutect2, varscan2
- OR5M10 | c.375C>A p.A125= | Silent (SNP) | VAF 32/209 reads (15%) | called by muse, mutect2, varscan2
- PDRG1 | c.132G>C p.L44= | Silent (SNP) | VAF 24/211 reads (11%) | catalogued as COSV52430986, COSV52431920; called by muse, mutect2, varscan2
- PIDD1 | c.519C>T p.L173= | Silent (SNP) | VAF 12/67 reads (18%) | called by muse, mutect2, varscan2
- PRKDC | c.7527A>T p.G2509= | Silent (SNP) | VAF 26/294 reads (9%) | called by muse, mutect2
- PTCHD4 | c.1758G>A p.Q586= | Silent (SNP) | VAF 28/161 reads (17%) | catalogued as rs764172058, COSV99045023; called by muse, mutect2, varscan2
- PTK7 | c.534C>T p.V178= | Silent (SNP) | VAF 11/60 reads (18%) | catalogued as rs760032225; called by muse, mutect2, varscan2
- PWP1 | c.1227C>T p.Y409= | Silent (SNP) | VAF 68/248 reads (27%) | catalogued as rs367798858; called by muse, mutect2, varscan2
- RGL1 | c.1905G>T p.S635= (on ENST00000360851 / NM_001297672.2; = p.S670= on NM_015149.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 45/581 reads (8%) | catalogued as rs371789837; called by muse, mutect2
- RNPEPL1 | c.1308G>A p.L436= | Silent (SNP) | VAF 9/83 reads (11%) | catalogued as COSV54372940; called by muse, mutect2, varscan2
- SESN1 | c.205C>T p.L69= | Silent (SNP) | VAF 37/263 reads (14%) | catalogued as rs745513653; called by muse, mutect2, varscan2
- SETX | c.6585C>T p.L2195= | Silent (SNP) | VAF 78/393 reads (20%) | called by muse, mutect2, varscan2
- SOCS6 | c.219G>A p.L73= | Silent (SNP) | VAF 44/364 reads (12%) | catalogued as COSV67546240; called by muse, mutect2, varscan2
- SPCS1 | c.126C>G p.L42= | Silent (SNP) | VAF 28/150 reads (19%) | called by muse, mutect2, varscan2
- SPOCK1 | c.745C>T p.L249= | Silent (SNP) | VAF 9/83 reads (11%) | catalogued as rs1018868939; called by muse, mutect2, varscan2
- TAAR9 | c.417C>A p.T139= | Silent (SNP) | VAF 25/132 reads (19%) | catalogued as rs771182878; called by muse, mutect2, varscan2
- TC2N | c.975A>G p.S325= | Silent (SNP) | VAF 28/290 reads (10%) | catalogued as rs377422447; called by muse, mutect2
- TGIF2LY | c.330G>T p.P110= | Silent (SNP) | VAF 29/224 reads (13%) | catalogued as COSV100339700; called by muse, mutect2, varscan2
- TIMM44 | c.360G>A p.K120= | Silent (SNP) | VAF 49/338 reads (14%) | called by muse, mutect2, varscan2
- TMEM272 | c.186C>T p.I62= | Silent (SNP) | VAF 18/297 reads (6%) | catalogued as rs900017169; called by muse, mutect2
- TOGARAM2 | c.963G>T p.T321= | Silent (SNP) | VAF 25/233 reads (11%) | called by muse, mutect2, varscan2
- TOX2 | c.276G>T p.L92= (on ENST00000358131 / NM_001098798.2; = p.L41= on NM_032883.3) | Silent (SNP) | VAF 28/185 reads (15%) | called by muse, mutect2
- TRAF2 | c.1278C>T p.F426= | Silent (SNP) | VAF 12/51 reads (24%) | called by muse, mutect2, varscan2
- UNC80 | c.6912G>T p.L2304= | Silent (SNP) | VAF 38/420 reads (9%) | called by muse, mutect2
- WNT4 | c.123G>A p.E41= | Silent (SNP) | VAF 34/284 reads (12%) | catalogued as rs746248932; called by muse, mutect2, varscan2
- YEATS2 | c.2622A>G p.K874= | Silent (SNP) | VAF 40/211 reads (19%) | called by muse, mutect2, varscan2
- ZNF729 | c.2205T>A p.T735= | Silent (SNP) | VAF 46/344 reads (13%) | catalogued as COSV100675533; called by muse, mutect2, varscan2
- ABCG5 | c.502-275G>C | Intron (SNP) | VAF 4/56 reads (7%) | catalogued as rs1250946261; called by muse, mutect2
- AC093791.1 | n.365C>A | RNA (SNP) | VAF 33/287 reads (11%) | called by muse, mutect2, varscan2
- APTX | c.133+167C>G | Intron (SNP) | VAF 26/190 reads (14%) | catalogued as rs754928641; called by muse, mutect2, varscan2
- C2orf68 | c.226+26C>G | Intron (SNP) | VAF 7/69 reads (10%) | called by muse, mutect2, varscan2
- CCDC116 | c.-23C>G | 5'UTR (SNP) | VAF 27/162 reads (17%) | called by muse, mutect2, varscan2
- CHIT1 | c.*535T>A | 3'UTR (SNP) | VAF 27/214 reads (13%) | called by muse, mutect2, varscan2
- CLK2P1 | n.918A>G | RNA (SNP) | VAF 40/279 reads (14%) | called by muse, mutect2, varscan2
- CRB1 | c.4005+28C>T | Intron (SNP) | VAF 39/353 reads (11%) | catalogued as COSV100958055; called by muse, mutect2, varscan2
- DCHS2 | n.7823C>T | RNA (SNP) | VAF 27/197 reads (14%) | catalogued as rs761139903; called by muse, mutect2, varscan2
- DZANK1 | c.379-89A>T | Intron (SNP) | VAF 38/378 reads (10%) | called by muse, mutect2
- FBXW10 | c.871+21G>A | Intron (SNP) | VAF 14/147 reads (10%) | called by muse, mutect2
- FER1L4 | n.2617G>A | RNA (SNP) | VAF 5/47 reads (11%) | called by muse, mutect2, varscan2
- FLI1 | c.385+79C>G | Intron (SNP) | VAF 5/44 reads (11%) | catalogued as rs1192376050; called by muse, mutect2, varscan2
- GNRHR | c.*29A>C | 3'UTR (SNP) | VAF 13/127 reads (10%) | called by muse, mutect2
- GVINP1 | n.1983T>A | RNA (SNP) | VAF 10/65 reads (15%) | called by mutect2, varscan2
- ISCU | c.418+415G>C | Intron (SNP) | VAF 22/282 reads (8%) | called by muse, mutect2
- ISOC2 | c.349-31G>A | Intron (SNP) | VAF 38/81 reads (47%) | catalogued as rs376381485; called by muse, mutect2, varscan2
- KAT6A | c.1483-1807G>A | Intron (SNP) | VAF 43/334 reads (13%) | called by muse, mutect2, varscan2
- NDRG2 | c.408-148C>T | Intron (SNP) | VAF 13/90 reads (14%) | called by muse, mutect2, varscan2
- NDUFA2 | c.101+34G>A | Intron (SNP) | VAF 13/103 reads (13%) | called by muse, mutect2, varscan2
- NECTIN3-AS1 | n.823C>G | RNA (SNP) | VAF 40/462 reads (9%) | called by muse, mutect2
- NEURL1B | c.-41G>A | 5'UTR (SNP) | VAF 6/53 reads (11%) | called by muse, mutect2
- OR6W1P | n.806A>G | RNA (SNP) | VAF 25/150 reads (17%) | called by muse, mutect2, varscan2
- PABPN1 | c.352-37C>A | Intron (SNP) | VAF 9/116 reads (8%) | called by muse, mutect2
- PMS2 | chr7:6009066 G>A | 5'Flank (SNP) | VAF 36/188 reads (19%) | called by muse, mutect2, varscan2
- PNKD | c.236+1118C>T | Intron (SNP) | VAF 27/207 reads (13%) | catalogued as rs199646553; called by muse, mutect2, varscan2
- PPP2R5C | c.630-276G>A | Intron (SNP) | VAF 14/76 reads (18%) | called by muse, mutect2, varscan2
- PTPDC1 | c.83-545T>A | Intron (SNP) | VAF 11/76 reads (14%) | called by muse, mutect2, varscan2
- SPAG16 | c.184-179A>G | Intron (SNP) | VAF 10/143 reads (7%) | called by muse, mutect2
- ST8SIA1 | c.585-21708G>C | Intron (SNP) | VAF 14/96 reads (15%) | called by muse, mutect2
- TP53AIP1 | c.141+154del | Intron (DEL) | VAF 5/27 reads (19%) | catalogued as rs1216454466; called by mutect2, pindel, varscan2
- TTC19 | c.*913C>T | 3'UTR (SNP) | VAF 38/291 reads (13%) | called by muse, mutect2, varscan2
- UBAP2L | c.2902+1440G>T | Intron (SNP) | VAF 36/408 reads (9%) | called by muse, mutect2
- ZNF57 | chr19:2896948 G>A | 5'Flank (SNP) | VAF 26/232 reads (11%) | catalogued as rs772359190; called by muse, mutect2
- ZNF772 | c.72+120T>C | Intron (SNP) | VAF 18/44 reads (41%) | called by muse, mutect2, varscan2
